Gene-level copy-number profile of tumor specimen TCGA-2G-AAI4-01A from TCGA case TCGA-2G-AAI4, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 26.9 years (9,812 days).
Specimen TCGA-2G-AAI4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 15f08939-1601-4d56-a70b-baf32e704d3d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAI4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/2ef8d97a-1c65-416e-9a87-00125d104d3c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,627; copy number 2: 18,955; copy number 3: 30,655; copy number 4: 5,845; copy number 5: 470; copy number 6: 334; copy number 7: 887; copy number 9: 97; copy number 10: 38.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,022 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:57,855,500–71,228,629, 191 genes, copy number 7–10 (within-gene range 3–10) (broad region; genes not listed).
- chr12:66,767–34,249,958, 831 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,115. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
